Somatic mutation profile of tumor specimen TCGA-QT-A5XK-01A (aliquot TCGA-QT-A5XK-01A-11D-A35D-08) from TCGA case TCGA-QT-A5XK, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 56.7 years (20,724 days).
Specimen TCGA-QT-A5XK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66eb6cda-5a27-41ce-bbdc-921dfbdea87f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QT-A5XK-10A (Blood Derived Normal), aliquot TCGA-QT-A5XK-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d54035d-ac1c-4ce6-aecc-ec614c257629

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RET | c.2753T>C p.M918T | Missense Mutation (SNP) | VAF 59/206 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74799832, CM941246, COSV60685905; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FNDC3A | c.2110A>G p.I704V (on ENST00000492622 / NM_001079673.2; = p.I648V on NM_014923.5) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs373752125; called by muse, mutect2, varscan2
- ANGPTL2 | c.770C>G p.T257S | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PSMA7 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 65/168 reads (39%) | called by muse, mutect2, varscan2
- HRG | c.1386T>C p.P462= | Silent (SNP) | VAF 42/72 reads (58%) | called by muse, mutect2, varscan2
- IMMP1L | c.250A>C p.R84= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- PCDHB5 | c.2229C>T p.T743= | Silent (SNP) | VAF 30/314 reads (10%) | called by muse, mutect2
